Gene-level copy-number profile of tumor specimen TCGA-AR-A1AI-01A from TCGA case TCGA-AR-A1AI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Medullary carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 47.2 years (17,229 days).
Specimen TCGA-AR-A1AI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.68564280-daf0-4bbb-9aa0-79493b39231b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A1AI-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/62259b2c-a031-4d0b-bc9a-9e8a35bdac61

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 2,499; copy number 2: 19,511; copy number 3: 15,231; copy number 4: 17,529; copy number 5: 2,282; copy number 6: 1,798; copy number 7: 357; copy number 8: 42; copy number 10: 500; copy number 11: 47.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A1AI-01A-11D-A12N-01): tumor purity 0.38, ploidy 3.17, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,659,613–88,584,530, 12 genes (within-gene range 0–4): PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS.
- chr14:43,274,824–43,596,683, 6 genes: TUBBP3, HNRNPUP1, AL583809.1, KRT8P2, AL358913.1, ARHGAP16P.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 547 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–32,888,145, 497 genes, copy number 10 (broad region; genes not listed).
- chr5:32,947,443–33,026,025, 3 genes, copy number 10: LINC02120, AC034223.1, AC034223.2.
- chr6:36,672,838–36,687,337, 5 genes, copy number 11: Y_RNA, PANDAR, LAP3P2, CDKN1A, DINOL.
- chr21:44,627,093–45,513,720, 42 genes, copy number 11 (within-gene range 8–11): KRTAP10-9, KRTAP10-10, KRTAP10-11, KRTAP12-4, KRTAP12-3, KRTAP12-2, IMMTP1, KRTAP12-1, KRTAP12-6P, KRTAP10-12, KRTAP10-13P, UBE2G2, LINC01424, SUMO3, PTTG1IP, ITGB2, ITGB2-AS1, AL844908.2, LINC01547, AL844908.1, FAM207A, AP001505.1, LINC00163, LINC00165, PICSAR, SSR4P1, ADARB1, AL133499.1, LINC00334, POFUT2, LINC00205, BX322557.2, LINC00315, BX322557.1, LINC00316, MTCO1P3, BX322559.1, BX322562.1, COL18A1, COL18A1-AS2, COL18A1-AS1, MIR6815.

Autosomal genes at a single copy (total copy number 1): 2,499. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
